Somatic mutation profile of tumor specimen 0DELKA from CCDI case PBBNZJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.7 years (1,712 days).
Specimen 0DELKA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13c28a79-5aed-4636-a4d2-9d60428461ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DELJ1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/612d6f77-3ada-4af6-ae47-3793e4577bff

The open-access MAF lists 8 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, Intron 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLAMF7 | c.550T>A p.W184R | Missense Mutation (SNP) | VAF 66/1104 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs141021747; called by muse, mutect2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 62/1746 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- KIR3DL2 | c.952A>T p.N318Y | Missense Mutation (SNP) | VAF 173/817 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- FAT2 | c.9741C>T p.G3247= | Silent (SNP) | VAF 314/832 reads (38%) | catalogued as rs772008822; called by muse, mutect2, varscan2
- SLC45A4 | c.2334G>A p.S778= (on ENST00000517878 / NM_001286646.2; = p.R725H on NM_001080431.2) | Silent (SNP) | VAF 227/643 reads (35%) | catalogued as rs373975040; called by muse, mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 14/160 reads (9%) | called by muse, varscan2
- CALCOCO2 | c.825+77T>A | Intron (SNP) | VAF 14/158 reads (9%) | called by muse, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 26/248 reads (10%) | called by muse, varscan2
